Surgical pathology report (de-identified scan), TCGA case TCGA-EA-A556, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Asterand, specimen TCGA-EA-A556-01A (Primary Tumor).

Gross Description:

Microscopic Description:

Diagnosis Details:

Comments:

Formatted Path Reports: CERVIX TISSUE CHECKLIST

Specimen type: Excision of tumor

Tumor site: Endocervix

Tumor size: 4 x 3.5 x 3 cm

Histologic type: Endometrioid adenocarcinoma

Histologic grade: Poorly differentiated

Tumor extent: Lesion less than 4.0 cm

Lymph nodes: 0/7 positive for metastasis (Regional 0/7)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: IHC demonstrated CA125, vimentin, CK7, high molecular weight cytokeratin - positive; PR - 30%. Some nuclei express neurospecific enolase, synaptophysin, chromogranin A, P63

ICD-0-3
adenocarcinoma, endometrioid, NOS 8380/3
Site: Cervix, NOS C53.9

hw
11/24/12

Case/Specimen	QUALIFIED	UNQUALIFIED
Reviewed	11/19/12	

Source: NCI Genomic Data Commons file 0026e187-c3f9-45dc-ad45-18223f7aa19f (TCGA-EA-A556.EDEF2B45-54BF-4329-B7ED-FBF59E13B438.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).